Somatic mutation profile of tumor specimen TCGA-EB-A4P0-01A (aliquot TCGA-EB-A4P0-01A-41D-A25O-08) from TCGA case TCGA-EB-A4P0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 82.8 years (30,225 days).
Specimen TCGA-EB-A4P0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec7d6b7-0cb7-411c-8dec-0be479835fda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4P0-10A (Blood Derived Normal), aliquot TCGA-EB-A4P0-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c18bb685-75ba-4a99-85c4-cf34e9d8763a

The open-access MAF lists 236 somatic variants for this specimen: 144 protein-altering or splice-affecting, 86 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 86, Nonsense Mutation 5, Intron 3, Splice Region 3, RNA 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCG8 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV55391115; called by muse, mutect2, varscan2
- ACSS2 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53623089; called by muse, mutect2
- ADAM2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs763431627, COSV55859403; called by muse, mutect2, varscan2
- ADGRD1 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs754374268, COSV55439922; called by muse, mutect2, varscan2
- AGBL1 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV66850328; called by muse, mutect2, varscan2
- ALDH1L1 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1294872707, COSV56411252; called by muse, mutect2, varscan2
- AMPH | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57734569; called by muse, mutect2, varscan2
- ANXA13 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as COSV51621498; called by muse, mutect2, varscan2
- APOL5 | c.365C>A p.T122N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs572416546, COSV50766410; called by muse, mutect2, varscan2
- ARMC5 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV51654988; called by muse, mutect2
- BMP5 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701302; called by muse, mutect2, varscan2
- CACNA1A | c.3765G>A p.M1255I | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV64191235; called by muse, mutect2, varscan2
- CACNG7 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1054266739, COSV55813159; called by muse, mutect2, varscan2
- CACNG7 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1427201663, COSV55813167; called by muse, mutect2, varscan2
- CAMP | c.295G>A p.D99N (on ENST00000296435; = p.D96N on NM_004345.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV56481783; called by muse, mutect2, varscan2
- CANX | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56002862; called by muse, mutect2, varscan2
- CAPN9 | c.1482G>A p.R494= | Splice Region (SNP) | VAF 118/354 reads (33%) | catalogued as COSV55231102; called by muse, mutect2, varscan2
- CCDC73 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58796036; called by muse, mutect2
- CCDC93 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV60119840; called by muse, mutect2, varscan2
- CCR3 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371704270; called by muse, mutect2, varscan2
- CDS1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV55686805; called by muse, mutect2, varscan2
- CENPJ | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV67883063; called by muse, mutect2, varscan2
- CEP126 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV54822204; called by muse, mutect2, varscan2
- CEP70 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53874525; called by muse, mutect2, varscan2
- CFAP74 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.043); catalogued as COSV54565132; called by muse, mutect2, varscan2
- COL12A1 | c.1974T>G p.N658K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59390651; called by muse, mutect2, varscan2
- COL22A1 | c.4685G>A p.G1562E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57325806; called by muse, mutect2, varscan2
- CPNE4 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV70190644; called by muse, mutect2, varscan2
- CSTL1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55677714, COSV55678590; called by muse, mutect2, varscan2
- CTNNA2 | c.670T>G p.S224A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV63549942; called by muse, mutect2, varscan2
- CYP2B6 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57845374; called by muse, mutect2, varscan2
- CYP2C8 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748167187, COSV64876214; called by muse, mutect2, varscan2
- DAG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV58182897; called by muse, mutect2, varscan2
- DDIAS | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV61271619; called by muse, mutect2, varscan2
- DNAH17 | c.7714C>T p.P2572S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101101987; called by muse, mutect2
- DNAH3 | c.8620A>C p.I2874L | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV54506739; called by muse, mutect2, varscan2
- ENAH | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.986); catalogued as COSV52865538; called by muse, mutect2, varscan2
- ERP44 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52430049; called by muse, mutect2, varscan2
- F5 | c.1299C>T p.I433= | Splice Region (SNP) | VAF 33/61 reads (54%) | catalogued as rs541673477, COSV63121250; called by muse, mutect2, varscan2
- F7 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV60645133; called by muse, mutect2, varscan2
- FAM13C | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53244054; called by muse, mutect2, varscan2
- FARP2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV50869368; called by muse, mutect2
- FCRL1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV63824062; called by muse, mutect2, varscan2
- FHDC1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52598066; called by muse, mutect2, varscan2
- FPR3 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328483; called by muse, mutect2, varscan2
- GALNT6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV62541747; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, mutect2, varscan2
- GNAS | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV58328861; called by muse, mutect2, varscan2
- GNPDA2 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54946126; called by muse, mutect2, varscan2
- GRM6 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV51435123; called by muse, mutect2, varscan2
- GTF3C1 | c.2795A>T p.E932V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV62239287; called by muse, mutect2, varscan2
- HKDC1 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV63575716; called by muse, mutect2, varscan2
- HTT | c.8195C>T p.P2732L | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV61858159; called by muse, mutect2, varscan2
- IGSF9 | c.3205G>A p.E1069K (on ENST00000368094 / NM_001135050.2; = p.E1053K on NM_020789.4) | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as rs1452152740, COSV57421731; called by muse, mutect2, varscan2
- IL13RA1 | c.285T>G p.C95W | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65426113; called by muse, mutect2, varscan2
- IL31RA | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51679738; called by muse, mutect2, varscan2
- ISL1 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV57932623; called by muse, mutect2, varscan2
- KCNG1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs1316395629, COSV65368131; called by muse, mutect2, varscan2
- KLHL1 | c.2206G>T p.G736W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64767761; called by muse, mutect2, varscan2
- KMT2E | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | catalogued as COSV57570068; called by muse, mutect2, varscan2
- KRT9 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.988); catalogued as rs758348502, COSV55851658, COSV99879082; called by muse, mutect2, varscan2
- L3MBTL4 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs749722357, COSV53114604; called by muse, mutect2, varscan2
- LCN1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.7); PolyPhen benign (0.028); catalogued as rs746251906, COSV55017205; called by muse, mutect2, varscan2
- LHFPL5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 101/191 reads (53%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.698); catalogued as COSV64177227; called by muse, mutect2, varscan2
- LIMCH1 | c.345G>A p.K115= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs867998227, COSV58275472; called by muse, mutect2, varscan2
- LNX2 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs991667447, COSV60334454; called by muse, mutect2, varscan2
- LOXL2 | c.1682C>T p.T561I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as COSV66690529; called by muse, mutect2, varscan2
- LRBA | c.7819A>G p.N2607D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV63950653; called by muse, mutect2, varscan2
- MAGEC1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 74/81 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs751959644, COSV53568902; called by muse, mutect2, varscan2
- MAMLD1 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV53372456; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2804C>G p.P935R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV51716950; called by muse, mutect2, varscan2
- MCTP2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59141447; called by muse, mutect2, varscan2
- MGA | c.7388T>A p.I2463N (on ENST00000219905 / NM_001164273.1; = p.I2254N on NM_001080541.2) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54949776; called by muse, mutect2, varscan2
- MLIP | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51426606; called by muse, mutect2, varscan2
- MMP19 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.604); catalogued as COSV59450428; called by muse, mutect2, varscan2
- MUC16 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV67448738; called by muse, mutect2, varscan2
- MYC | c.175C>T p.P59S (on ENST00000377970; = p.P74S on NM_002467.6) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52367409, COSV52367643, COSV52370791; called by muse, mutect2, varscan2
- MYH2 | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV55432663; called by muse, mutect2, varscan2
- NAA60 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62654288; called by muse, mutect2, varscan2
- NAIP | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99519237; called by muse, mutect2, varscan2
- NEXN | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53941980; called by muse, mutect2, varscan2
- NLRP5 | c.675A>C p.E225D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV66762473, COSV66766473; called by muse, mutect2, varscan2
- OR10R2 | c.253A>C p.I85L | Missense Mutation (SNP) | VAF 113/218 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV63768526; called by muse, mutect2, varscan2
- OR11A1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV65820728; called by muse, mutect2, varscan2
- OR1S1 | c.142T>A p.Y48N | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58706148; called by muse, mutect2, varscan2
- OR4A47 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV71444854; called by muse, mutect2, varscan2
- OR4K2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53847918, COSV53848106; called by muse, mutect2, varscan2
- PAN2 | c.3103G>C p.V1035L (on ENST00000425394 / NM_001127460.3; = p.V1031L on NM_014871.5) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56263926; called by muse, mutect2, varscan2
- PATJ | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57156614; called by muse, mutect2, varscan2
- PCDHA3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65364530; called by muse, mutect2, varscan2
- PCDHA6 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65349881; called by muse, mutect2, varscan2
- PCDHGA10 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV53907538; called by muse, mutect2, varscan2
- PKHD1L1 | c.4429C>T p.H1477Y | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65738450; called by muse, mutect2, varscan2
- PLCD1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1333386693, COSV58159681; called by muse, mutect2, varscan2
- PLD2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752760973, COSV54003899, COSV99562287; called by muse, mutect2, varscan2
- PLEKHH3 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV53188099; called by muse, mutect2, varscan2
- POLR2B | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.653); catalogued as rs1168013610, COSV58898862; called by muse, mutect2, varscan2
- PPFIBP1 | c.2957T>G p.L986* (on ENST00000318304 / NM_177444.3; = p.L980* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57288276; called by muse, mutect2, varscan2
- PPP4C | c.265T>A p.Y89N | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV54221171; called by muse, mutect2, varscan2
- PTPRN2 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66104654; called by muse, mutect2, varscan2
- RFTN1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1306849275, COSV61917140; called by muse, mutect2, varscan2
- RNF17 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55035060, COSV55045829; called by muse, mutect2, varscan2
- RORC | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV59091741; called by muse, mutect2, varscan2
- RP1 | c.2461C>T p.H821Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV55111203; called by muse, mutect2, varscan2
- RPL13A | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs377252495, COSV99201349; called by muse, mutect2, varscan2
- RPL7 | c.424T>A p.W142R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV53581436; called by muse, mutect2, varscan2
- RTKN | c.1666C>T p.R556C (on ENST00000272430 / NM_001015055.2; = p.R543C on NM_033046.2) | Missense Mutation (SNP) | VAF 92/171 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs1253780029, COSV51961727; called by muse, mutect2, varscan2
- SEPTIN14 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs1176840270, COSV66426401; called by muse, mutect2, varscan2
- SLC11A1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143475636, COSV51915928; called by muse, mutect2, varscan2
- SLC26A8 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV62884747; called by muse, mutect2, varscan2
- SLC28A2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61663382; called by muse, mutect2, varscan2
- SLC9A2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as COSV52129311, COSV99296902; called by muse, mutect2, varscan2
- SMARCD3 | c.1196T>C p.I399T (on ENST00000262188 / NM_001003801.2; = p.I386T on NM_003078.4) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50389221; called by muse, mutect2, varscan2
- SORL1 | c.6148G>A p.E2050K | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV52750180; called by muse, mutect2, varscan2
- SPEF2 | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57427309; called by muse, mutect2, varscan2
- SPRR2B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV58796860, COSV58796954; called by muse, mutect2, varscan2
- SPTBN5 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1410644273, COSV100311172; called by muse, mutect2, varscan2
- SULF2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs781289441, COSV100737133; called by muse, mutect2, varscan2
- TCF23 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56077988; called by muse, mutect2, varscan2
- TIAM2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.92); catalogued as COSV59690220; called by muse, mutect2, varscan2
- TLR9 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs145698725; called by muse, mutect2, varscan2
- TMEM154 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV58589997, COSV58591294; called by muse, mutect2, varscan2
- TPTE2 | c.548T>A p.I183N (on ENST00000400230 / NM_199254.2; = p.I106N on NM_130785.3) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99690115; called by muse, mutect2, varscan2
- TRIM29 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59279238; called by muse, mutect2
- TRIM36 | c.1957A>G p.N653D | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.6); PolyPhen benign (0.102); catalogued as COSV56688456; called by muse, mutect2, varscan2
- TRPM8 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201672489, COSV61220910; called by muse, mutect2, varscan2
- TRRAP | c.5837C>T p.T1946I (on ENST00000359863 / NM_001244580.1; = p.T1928I on NM_003496.3) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100722327; called by muse, mutect2, varscan2
- TTPA | c.553-1G>A p.X185_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | catalogued as COSV52645930, COSV99478467; called by muse, mutect2, varscan2
- TUBGCP6 | c.4807G>A p.E1603K | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50537843; called by muse, mutect2, varscan2
- UBAC1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.286); catalogued as COSV65613756; called by muse, mutect2, varscan2
- UBXN4 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV55633612; called by muse, mutect2, varscan2
- UMOD | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV56773925; called by muse, mutect2, varscan2
- USP14 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs201975297, COSV55279199; called by muse, mutect2, varscan2
- USP43 | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 57/135 reads (42%) | catalogued as rs747645380, COSV53300190; called by muse, mutect2, varscan2
- UVRAG | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1367824783, COSV62101775; called by muse, mutect2, varscan2
- VNN1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63389412; called by muse, mutect2, varscan2
- VPS13B | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62134699; called by muse, mutect2
- XAGE5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs782176167, COSV100657828, COSV63567636; called by muse, mutect2, varscan2
- XIRP2 | c.5339G>A p.G1780E (on ENST00000628543; = p.G1955E on NM_152381.6) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54681275; called by muse, mutect2, varscan2
- ZFYVE28 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as rs763072682, COSV52108128; called by muse, mutect2, varscan2
- ZNF385D | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1401991191, COSV55747466; called by muse, mutect2, varscan2
- IGHG1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIR3DL3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANGPT1 | c.681A>C p.T227= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV52432203; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1764C>T p.I588= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV52871132; called by muse, mutect2, varscan2
- BAHD1 | c.2316C>T p.H772= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs768737498, COSV60378432; called by muse, mutect2, varscan2
- BCAR1 | c.2502C>T p.A834= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV50779032; called by muse, mutect2, varscan2
- BPIFB4 | c.1063C>T p.L355= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs755182899, COSV64950796; called by muse, mutect2, varscan2
- CDCP1 | c.703C>T p.L235= | Silent (SNP) | VAF 87/174 reads (50%) | catalogued as rs748696771, COSV56104018; called by muse, mutect2, varscan2
- CES3 | c.357C>T p.S119= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs773828115, COSV57592812; called by muse, mutect2, varscan2
- CFAP74 | c.2160G>A p.E720= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- CFAP92 | c.309C>T p.H103= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV54046471; called by muse, mutect2, varscan2
- CNGA3 | c.847C>A p.R283= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as CM980376, COSV55622680; called by muse, mutect2, varscan2
- COL9A1 | c.2205G>A p.R735= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1005817817, COSV57879713; called by muse, mutect2, varscan2
- CSMD1 | c.4362G>A p.G1454= (on ENST00000520002; = p.G1453= on NM_033225.6) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1016527894, COSV59288552; called by muse, mutect2, varscan2
- CYP2B6 | c.1332G>A p.A444= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs775699069, COSV57843381, COSV57845714; called by muse, mutect2, varscan2
- DAPK3 | c.78C>T p.I26= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs767022591, COSV56662273; called by muse, mutect2, varscan2
- DNAH17 | c.7713C>T p.N2571= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101101989; called by muse, mutect2
- DNAH5 | c.1179C>T p.I393= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV54207534, COSV54242204; called by muse, mutect2, varscan2
- DNAI2 | c.1461C>T p.T487= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56757098; called by muse, mutect2, varscan2
- DPP9 | c.1326C>T p.L442= (on ENST00000598800; = p.L471= on NM_139159.5) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV53589492; called by muse, mutect2, varscan2
- DST | c.351C>T p.I117= | Silent (SNP) | VAF 84/229 reads (37%) | called by muse, mutect2, varscan2
- E2F7 | c.1539C>T p.S513= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as COSV59737711; called by muse, mutect2, varscan2
- FABP1 | c.228G>A p.G76= | Silent (SNP) | VAF 94/168 reads (56%) | catalogued as COSV55557966; called by muse, mutect2, varscan2
- FGF3 | c.684G>A p.S228= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs781790410, COSV61925321; called by muse, mutect2
- FNBP4 | c.2172C>T p.P724= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55446675; called by muse, mutect2, varscan2
- FOSL2 | c.162C>T p.I54= | Silent (SNP) | VAF 36/59 reads (61%) | catalogued as COSV53103564; called by muse, mutect2, varscan2
- FXR2 | c.577C>T p.L193= | Silent (SNP) | VAF 61/174 reads (35%) | catalogued as COSV51517738, COSV51519290; called by muse, varscan2
- GCHFR | c.60C>T p.G20= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs376405201; called by muse, mutect2, varscan2
- GFRA1 | c.756G>A p.T252= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV62602744; called by muse, mutect2, varscan2
- GJC1 | c.288C>T p.I96= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as rs750455856, COSV57910553; called by muse, mutect2, varscan2
- GPCPD1 | c.1275G>A p.V425= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV66830268; called by muse, mutect2
- GRM7 | c.1473T>C p.G491= | Silent (SNP) | VAF 49/80 reads (61%) | catalogued as COSV63131674; called by muse, mutect2, varscan2
- HASPIN | c.660C>T p.S220= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV53990052; called by muse, mutect2, varscan2
- HMGCL | c.120C>T p.P40= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV52525223; called by muse, mutect2, varscan2
- IGSF21 | c.93G>A p.E31= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as COSV52126527; called by muse, mutect2, varscan2
- IL1A | c.234G>A p.G78= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV54518995; called by muse, mutect2, varscan2
- ITGA4 | c.1446G>A p.T482= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1356750924, COSV51998194; called by muse, mutect2, varscan2
- ITGAM | c.519C>T p.V173= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV54934479; called by muse, mutect2, varscan2
- KANK2 | c.1533A>C p.S511= (on ENST00000586659 / NM_001379562.1; = p.S519= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62006686; called by muse, mutect2, varscan2
- KLHL25 | c.1083C>T p.Y361= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs777887327, COSV61994307; called by muse, mutect2, varscan2
- LGR6 | c.1899A>C p.G633= (on ENST00000367278 / NM_001017403.1; = p.G581= on NM_021636.3) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55152294; called by muse, mutect2, varscan2
- LY6K | c.255C>T p.C85= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV52832067; called by muse, mutect2, varscan2
- MAGEC2 | c.582C>T p.G194= | Silent (SNP) | VAF 74/85 reads (87%) | catalogued as COSV55998146, COSV99909548; called by muse, mutect2, varscan2
- MAP6 | c.1239G>A p.A413= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs768825918, COSV59074485; called by muse, mutect2, varscan2
- MARCO | c.1440G>A p.Q480= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs149477153, COSV59052251; called by muse, mutect2, varscan2
- MBD5 | c.4425C>T p.I1475= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV68695929; called by muse, mutect2, varscan2
- MEX3B | c.1071C>T p.P357= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV61662929; called by muse, mutect2, varscan2
- MTA1 | c.2001G>A p.K667= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV58755885; called by muse, mutect2, varscan2
- MUC16 | c.42303C>T p.S14101= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV66690223; called by muse, mutect2, varscan2
- MYH1 | c.5115C>T p.I1705= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs145122906, COSV56844388; called by muse, mutect2, varscan2
- MYH6 | c.5187G>A p.K1729= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV62448274; called by muse, mutect2, varscan2
- MYOCD | c.2553C>T p.F851= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV58497519, COSV58498235; called by muse, mutect2, varscan2
- MYRF | c.1641G>A p.R547= (on ENST00000278836 / NM_001127392.3; = p.R538= on NM_013279.4) | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV53886432; called by muse, mutect2, varscan2
- NBN | c.891C>T p.L297= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs1554563793, COSV55371519; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP4 | c.1062G>A p.E354= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as COSV56708924; called by muse, mutect2, varscan2
- NRP2 | c.2787C>T p.S929= (on ENST00000360409 / NM_201266.2; = p.S924= on NM_003872.3) | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs761175695, COSV63370577; called by muse, mutect2
- OR6F1 | c.522C>T p.I174= | Silent (SNP) | VAF 73/130 reads (56%) | catalogued as COSV57467029; called by muse, mutect2, varscan2
- OSBPL10 | c.2163G>A p.K721= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as COSV67336776; called by muse, mutect2, varscan2
- OSTN | c.336A>G p.P112= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV59138991; called by muse, mutect2, varscan2
- PADI4 | c.1890C>T p.I630= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV64923123; called by muse, mutect2, varscan2
- PGLYRP4 | c.519C>T p.I173= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as COSV62834701; called by muse, mutect2, varscan2
- PIGS | c.978C>T p.L326= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV52023793; called by muse, mutect2, varscan2
- PLXNA1 | c.2958G>A p.L986= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52522815; called by muse, mutect2, varscan2
- PTPRK | c.2217G>A p.V739= (on ENST00000368215 / NM_001291984.2; = p.V740= on NM_002844.4) | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV63892025; called by muse, mutect2, varscan2
- R3HCC1L | c.1575C>T p.A525= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs765053075, COSV54399322; called by muse, mutect2, varscan2
- RAVER1 | c.486C>T p.F162= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV50328551; called by muse, mutect2, varscan2
- RELN | c.9945G>A p.R3315= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV58988085; called by muse, mutect2, varscan2
- RHOA | c.231C>T p.T77= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs375767122; called by muse, mutect2, varscan2
- RPL13A | c.174C>T p.L58= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99201296, COSV99201297; called by muse, mutect2, varscan2
- RTEL1 | c.207C>T p.A69= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs957858006, COSV58896180; called by muse, mutect2, varscan2
- SEC24B | c.2436G>A p.Q812= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV54495451, COSV54496091; called by muse, mutect2, varscan2
- SELP | c.1725C>T p.L575= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55248920; called by muse, mutect2, varscan2
- SLC13A2 | c.1332G>A p.L444= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs1555604486, COSV58993009; called by muse, mutect2, varscan2
- SLC4A4 | c.981C>T p.L327= (on ENST00000264485 / NM_001098484.3; = p.L283= on NM_003759.4) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV52616299; called by muse, mutect2, varscan2
- SLC5A7 | c.222A>T p.A74= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV50889228; called by muse, mutect2, varscan2
- SPTAN1 | c.138C>T p.F46= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV63985682; called by muse, mutect2, varscan2
- SSUH2 | c.936C>T p.I312= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as COSV58029224, COSV58033353; called by muse, mutect2, varscan2
- STARD8 | c.1728C>T p.I576= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV52922565; called by muse, mutect2, varscan2
- SULF2 | c.465C>A p.P155= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100737131; called by muse, mutect2, varscan2
- SYNJ2 | c.1350G>A p.G450= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV62895854; called by muse, mutect2, varscan2
- TKTL2 | c.1599C>T p.V533= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV54917646; called by muse, mutect2, varscan2
- TRRAP | c.5838C>T p.T1946= (on ENST00000359863 / NM_001244580.1; = p.T1928= on NM_003496.3) | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100722329; called by muse, mutect2, varscan2
- TSLP | c.45G>A p.R15= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV61291338; called by muse, mutect2, varscan2
- TSPOAP1 | c.3162G>A p.E1054= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs772114369, COSV52105061; called by muse, mutect2, varscan2
- YIPF5 | c.153C>T p.V51= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV50822927; called by muse, mutect2, varscan2
- ZNF692 | c.432G>A p.R144= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as COSV60658771; called by muse, mutect2, varscan2
- ZNF831 | c.888A>G p.Q296= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV64037918; called by muse, mutect2, varscan2
- ZSWIM2 | c.261C>T p.F87= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54574056, COSV99719970; called by muse, mutect2, varscan2
- AGAP7P | n.1587G>T | RNA (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1133+32A>T | Intron (SNP) | VAF 100/262 reads (38%) | catalogued as COSV100527890; called by muse, mutect2
- CHRM2 | c.-47+33772G>A | Intron (SNP) | VAF 42/108 reads (39%) | catalogued as COSV100281105; called by muse, mutect2, varscan2
- LINC01565 | n.1303C>T | RNA (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+66A>G | Intron (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100000253; called by muse, mutect2, varscan2
- UBTFL2 | n.546G>A | RNA (SNP) | VAF 5/20 reads (25%) | called by mutect2, varscan2
